Gene-level copy-number profile of tumor specimen TCGA-KK-A6E8-01A from TCGA case TCGA-KK-A6E8, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 68.5 years (25,026 days).
Specimen TCGA-KK-A6E8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.8224eed4-93b3-42b9-bfd0-a13c90b7d7b5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KK-A6E8-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e2457b2f-a2c3-4cce-a847-34e66bbb2c0a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 52; copy number 1: 6,984; copy number 2: 43,751; copy number 3: 7,465; copy number 4: 33; copy number 5: 214; copy number 6: 1,290; copy number 7: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KK-A6E8-01A-11D-A31K-01): tumor purity 0.84, ploidy 2.14, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:136,544,712–137,677,718, 2 genes (within-gene range 0–1): SMC4P1, THSD7B.
- chr2:140,231,423–142,131,016, 1 gene (within-gene range 0–1): LRP1B.
- chr2:140,586,626–141,208,376, 6 genes: MIR7157, COPRSP1, LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.
- chr3:159,282,646–159,282,734, 1 gene: MIR3919.
- chr8:16,107,878–16,567,490, 3 genes: MSR1, CCT3P1, MRPL49P2.
- chr8:16,604,255–16,664,879, 1 gene (within-gene range 0–1): AC011586.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,534 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,636. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
